FM case AD12301 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/fe8e4133-c114-437e-8615-9869ec9be8f7

Male, 46.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
